Somatic mutation profile of tumor specimen TCGA-YL-A8SA-01A (aliquot TCGA-YL-A8SA-01A-21D-A377-08) from TCGA case TCGA-YL-A8SA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.4 years (25,340 days).
Specimen TCGA-YL-A8SA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e4f3d0b-55e4-4031-831f-b65be23cc0bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SA-10A (Blood Derived Normal), aliquot TCGA-YL-A8SA-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f5407e-ce15-46c3-9312-cec0f8e7c2f2

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD28 | c.1642A>T p.R548* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV101080276; called by muse, mutect2, varscan2
- ARHGAP36 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99357217; called by muse, mutect2, varscan2
- BMPER | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51811950, COSV99778853; called by muse, mutect2, varscan2
- CASS4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs142769327; called by muse, mutect2
- CIR1 | c.1121A>C p.K374T | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs1373459196, COSV100564857; called by muse, mutect2, varscan2
- DVL3 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1251783222, COSV99490304; called by muse, mutect2, varscan2
- EFCAB5 | c.4468T>C p.Y1490H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.187); catalogued as COSV100299775; called by muse, mutect2, varscan2
- FLG2 | c.6855G>T p.Q2285H | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV66170880; called by muse, mutect2, varscan2
- KIFC1 | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219238233, COSV100995979; called by muse, mutect2, varscan2
- MCM2 | c.1232A>G p.E411G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99412769; called by muse, mutect2, varscan2
- NDST4 | c.2094C>G p.D698E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as rs779070902, COSV99995412; called by muse, mutect2, varscan2
- PCDHB1 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV100128020; called by muse, mutect2, varscan2
- SPDYC | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs781661812, COSV101017118; called by muse, mutect2, varscan2
- SPINK5 | c.2768T>C p.I923T | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV99806102; called by muse, mutect2, varscan2
- SPTLC1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs143232538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCE2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV99535712; called by muse, mutect2, varscan2
- TBC1D32 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99249501; called by muse, mutect2, varscan2
- TJP2 | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99600562; called by muse, mutect2
- UBLCP1 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99707262; called by muse, mutect2, varscan2
- ZNF99 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV101233644, COSV68056562; called by muse, mutect2
- SCN2A | c.499del p.T167Lfs*15 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- C2orf16 | c.5022C>A p.S1674= | Silent (SNP) | VAF 68/168 reads (40%) | catalogued as rs878911663, COSV100820648; called by muse, mutect2, varscan2
- GJB4 | c.342G>A p.P114= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs146404415; called by muse, mutect2, varscan2
- HEATR5B | c.2086C>T p.L696= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99248212; called by muse, mutect2, varscan2
- MIA2 | c.723A>G p.K241= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99697275; called by muse, mutect2, varscan2
- PTN | c.387C>T p.A129= | Silent (SNP) | VAF 70/185 reads (38%) | catalogued as rs1291158175, COSV100780791; called by muse, mutect2, varscan2
- RMI1 | c.411G>T p.L137= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100366041; called by muse, mutect2, varscan2
- TRIM9 | c.816A>T p.L272= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100030454; called by muse, mutect2, varscan2
